Somatic mutation profile of tumor specimen HCM-BROD-0051-C64-06B (aliquot HCM-BROD-0051-C64-06B-01D-A79L-36) from HCMI case HCM-BROD-0051-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.6 years (941 days).
Specimen HCM-BROD-0051-C64-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fc97f65-6ac0-4ab6-91e4-883c44eb3524.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0051-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0051-C64-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8890ee42-ee4d-48fa-a453-16b6fa28e74f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF90 | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs186928119, COSV69001934, COSV69002776; called by muse, mutect2
- HNRNPUL2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 122/1894 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- ZMIZ1 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 32/764 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKS6 | c.18G>A p.L6= | Silent (SNP) | VAF 105/997 reads (11%) | catalogued as rs1487517964; called by muse, mutect2, varscan2
- ISLR2 | c.765G>A p.A255= | Silent (SNP) | VAF 98/1078 reads (9%) | catalogued as COSV62301972; called by muse, mutect2
- ARHGEF4 | chr2:130916225 C>T | 5'Flank (SNP) | VAF 175/2036 reads (9%) | called by muse, mutect2
